Gene-level copy-number profile of tumor specimen TCGA-25-1318-01A from TCGA case TCGA-25-1318, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.1 years (19,755 days).
Specimen TCGA-25-1318-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.376e5a23-7824-4935-b63c-454fc1c99627.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1318-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae237ff4-ce97-4796-8163-9941a9ee45a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,304; copy number 2: 27,902; copy number 3: 14,653; copy number 4: 122; copy number 5: 218; copy number 6: 58; copy number 7: 75; copy number 8: 223; copy number 9: 262.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1318-01): tumor purity 0.57, ploidy 7.33, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 836 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–119,001,405, 3 genes, copy number 5–7 (within-gene range 3–7): TBX15, AL139420.1, AL139420.2.
- chr3:117,672,154–117,997,592, 1 gene, copy number 5 (within-gene range 2–5): AC092691.1.
- chr5:18,908,866–21,032,845, 14 genes, copy number 5: AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1.
- chr8:99,527,826–145,066,685, 719 genes, copy number 5–9 (broad region; genes not listed).
- chr14:43,990,539–46,651,781, 34 genes, copy number 5–7: LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr14:46,960,423–46,997,174, 2 genes, copy number 7: AL359951.1, RPA2P1.
- chr20:34,833,575–36,528,637, 63 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,883. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
